CPTAC case C3N-01502 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/73f0fa81-42e4-40e4-902e-8f5a49a34d26

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Age at diagnosis: 75.4 years (27,522 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,695 days (4.6 years); Progression or recurrence: no; Days to last follow up: 1,695 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.6 cm (a second GDC size field records 1.2 cm); Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 16; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 384 days (1.1 years); Disease response: Complete Response.
- Days to follow up: 634 days (1.7 years); Disease response: Complete Response.
- Days to follow up: 1,049 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,278 days (3.5 years); Disease response: Complete Response.
- Days to follow up: 1,695 days (4.6 years); Disease response: Complete Response.
- Follow-up contact recording only the day: day 1,503.

Other clinical attributes
- Weight: 69 kg; Height: 170.2 cm; BMI: 23.82.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 6; Cigarettes per day: 20; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1963; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01502-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 218 mg; Time between excision and freezing: 38 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01502-21: Section location: Body and Tail; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3N-01502-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3N-01502-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
